Somatic mutation profile of tumor specimen TCGA-BP-4972-01A (aliquot TCGA-BP-4972-01A-01D-1462-08) from TCGA case TCGA-BP-4972, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 43.9 years (16,038 days).
Specimen TCGA-BP-4972-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 59232046-1807-4ff4-85b2-08c6c40edaa0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-4972-11A (Solid Tissue Normal), aliquot TCGA-BP-4972-11A-01D-1462-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8190ddef-fd50-4814-aa85-9c7609d51252

The open-access MAF lists 42 somatic variants for this specimen: 30 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 10, Frame Shift Del 3, Splice Site 2, Intron 2, Frame Shift Ins 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACP5 | c.403C>T p.P135S | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV54536574; called by muse, mutect2, varscan2
- ADAMTS9 | c.4294G>A p.E1432K | Missense Mutation (SNP) | VAF 88/189 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.155); catalogued as COSV55784364; called by muse, mutect2, varscan2
- ANK3 | c.10316T>C p.M3439T | Missense Mutation (SNP) | VAF 41/144 reads (28%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as rs1433103950, COSV55065445; called by muse, mutect2, varscan2
- B3GALT2 | c.690A>C p.K230N | Missense Mutation (SNP) | VAF 51/175 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66464204; called by muse, mutect2, varscan2
- CACNB1 | c.648G>A p.S216= | Splice Region (SNP) | VAF 28/102 reads (27%) | catalogued as rs777039909, COSV59999218; called by muse, mutect2, varscan2
- CIZ1 | c.1916C>T p.P639L | Missense Mutation (SNP) | VAF 47/166 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.449); catalogued as COSV52972782; called by muse, mutect2, varscan2
- DGLUCY | c.263G>T p.G88V | Missense Mutation (SNP) | VAF 45/160 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV54088000; called by muse, mutect2, varscan2
- GPRASP1 | c.1358G>T p.S453I | Missense Mutation (SNP) | VAF 58/224 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.091); catalogued as COSV64355940; called by muse, mutect2, varscan2
- HGS | c.1987T>C p.Y663H | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.472); catalogued as COSV61268635; called by muse, mutect2, varscan2
- HPGD | c.94-1G>T p.X32_splice | Splice Site (SNP) | VAF 86/212 reads (41%) | catalogued as COSV56663218; called by muse, mutect2, varscan2
- KCNJ3 | c.208G>T p.D70Y | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54534617, COSV54538785; called by muse, mutect2, varscan2
- KIAA0930 | c.245T>G p.V82G (on ENST00000336156 / NM_001009880.2; = p.V87G on NM_015264.2) | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.651); catalogued as COSV52663963; called by muse, mutect2, varscan2
- LRCH2 | c.1430C>A p.A477D | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV57753635; called by muse, varscan2
- MSH6 | c.1267C>A p.L423I | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.216); catalogued as rs587781657, COSV52282149, COSV99316157; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NFASC | c.3254T>C p.I1085T | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.034); catalogued as rs770474742, COSV58369921; called by muse, mutect2, varscan2
- NPHP4 | c.2980G>C p.V994L | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.124); catalogued as COSV65395851; called by muse, mutect2, varscan2
- NUP205 | c.386T>C p.L129S | Missense Mutation (SNP) | VAF 89/247 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53661435; called by muse, mutect2, varscan2
- PACSIN1 | c.1038-2A>C p.X346_splice | Splice Site (SNP) | VAF 64/187 reads (34%) | catalogued as COSV55061020; called by muse, mutect2, varscan2
- PCDHA6 | c.2191G>A p.A731T | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV65342970; called by muse, mutect2, varscan2
- PPM1L | c.661del p.D221Mfs*16 | Frame Shift Del (DEL) | VAF 56/171 reads (33%) | catalogued as COSV55561810; called by mutect2, varscan2
- RRP12 | c.3869A>G p.N1290S | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as COSV59669059; called by muse, mutect2, varscan2
- SALL1 | c.471C>G p.S157R | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV51759796; called by muse, varscan2
- SLITRK6 | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 64/207 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs867783526, COSV68390597; called by muse, mutect2, varscan2
- TCERG1L | c.935A>T p.K312I | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV64052064; called by muse, mutect2, varscan2
- USP17L2 | c.467G>A p.G156D | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.61); PolyPhen benign (0.414); catalogued as rs747513169, COSV61556096; called by muse, varscan2
- WASF3 | c.530G>T p.R177M | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58968042; called by muse, mutect2, varscan2
- DNAH1 | c.703del p.H235Mfs*11 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | called by mutect2, pindel, varscan2
- TTLL4 | c.1767dup p.G590Wfs*5 | Frame Shift Ins (INS) | VAF 78/251 reads (31%) | called by mutect2, pindel, varscan2
- TULP3 | c.354del p.A119Lfs*19 | Frame Shift Del (DEL) | VAF 39/144 reads (27%) | called by mutect2, pindel, varscan2
- ZNF714 | c.1369_1371del p.E457del | In Frame Del (DEL) | VAF 16/100 reads (16%) | called by pindel, varscan2
- AIFM1 | c.1464C>T p.P488= | Silent (SNP) | VAF 67/261 reads (26%) | catalogued as rs146608893, COSV54854254, COSV54855797; ClinVar: likely benign; called by muse, mutect2, varscan2
- COL4A5 | c.3069T>G p.P1023= | Silent (SNP) | VAF 17/131 reads (13%) | catalogued as COSV60355543, COSV60364774; called by muse, mutect2, varscan2
- EFNA1 | c.369A>G p.G123= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as rs1402259214, COSV57597289; called by muse, mutect2, varscan2
- LRRK1 | c.540G>A p.P180= | Silent (SNP) | VAF 33/97 reads (34%) | catalogued as rs200144474, COSV52617066; called by muse, mutect2, varscan2
- PLEKHA7 | c.1602C>T p.H534= | Silent (SNP) | VAF 27/68 reads (40%) | catalogued as rs757618492, COSV63047806; called by muse, mutect2, varscan2
- PTPRB | c.2511G>A p.V837= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as rs1291741008, COSV54244995; called by muse, mutect2, varscan2
- RIMS1 | c.3162A>G p.L1054= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs993752467, COSV53464972; called by muse, mutect2, varscan2
- SLC2A5 | c.114T>A p.A38= | Silent (SNP) | VAF 25/66 reads (38%) | catalogued as COSV66237202; called by muse, mutect2, varscan2
- TERT | c.2355G>T p.P785= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs545260840, COSV57223297, COSV57223758; called by muse, mutect2, varscan2
- TGM5 | c.297C>T p.S99= | Silent (SNP) | VAF 30/96 reads (31%) | catalogued as COSV55010704; called by muse, mutect2, varscan2
- ABCC10 | c.-11-9T>G | Intron (SNP) | VAF 4/23 reads (17%) | catalogued as COSV99766866; called by muse, mutect2, varscan2
- GFOD1 | c.253+16525A>G | Intron (SNP) | VAF 24/79 reads (30%) | catalogued as COSV64953270; called by muse, mutect2, varscan2
